Surgical pathology report (de-identified scan), TCGA case TCGA-DU-6402, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-6402-01A (Primary Tumor).

AGE/SEX [REDACTED]

DOB: [REDACTED]

SURGERY DATE: [REDACTED]

RECEIVE DATE: [REDACTED]

PATHOLOGICAL DIAGNOSIS:

- A. BRAIN, TEMPORAL LOBE, EXCISIONAL BIOPSIES: (ANAPLASTIC)
ASTROCYTOMA.
- B. BRAIN, TEMPORAL LOBE, EXCISION: [REDACTED] T.
SEE MICROSCOPIC AND COMMENT.
-

Operation/Specimen: Brain.

Clinical History and Pre-Op Dx: [REDACTED] with recent onset seizure. Has two brain lesions. Right temporal lobe lesion biopsy.

GROSS PATHOLOGY:

- A. Received fresh, two fragments, 2 x 1.5 x 0.8 cm in aggregate. Soft, pinkish-gray, translucent. All #1 and 2.

INTRAOPERATIVE CONSULTATION: Brain, temporal lobe: Astrocytoma, probably anaplastic.

B.

SPECIMEN: Right temporal lobe tumor.

FIXATIVE: None.

GENERAL: A 1.5 x 1.2 x 0.5 cm. gelatinous red-brown fragment; obvious gray-tan brain tissue not recognized.

SECTIONS: 3 - all.

[REDACTED] pc4 [REDACTED]

MICROSCOPIC: A. Portions of an infiltrative cellular neoplastic proliferation of astrocytic cells with moderate nuclear anaplasia, occasional mitotic figures, and abundant microvascular cellular proliferation.

B. Portions of a blood clot made of well preserved RBCs, and without lamination of fibrin.

ADDENDUM MICROSCOPIC: With immunostain for MIB-1, the proliferative index of the tumor cells is about 6%.

[REDACTED]

Source: NCI Genomic Data Commons file c8fdd299-70ac-4155-b2b4-f445aaa905d0 (TCGA-DU-6402.CF00FC85-C4BE-4D4A-987A-074FCF53ACA3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).